Somatic mutation profile of tumor specimen TCGA-34-5232-01A (aliquot TCGA-34-5232-01A-21D-1817-08) from TCGA case TCGA-34-5232, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 75.7 years (27,633 days).
Specimen TCGA-34-5232-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 229df2a1-8442-4fd9-b5de-60754de3d9ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-34-5232-10A (Blood Derived Normal), aliquot TCGA-34-5232-10A-01D-1817-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3322b523-2919-4ea6-8d11-f10c9ddc637f

The open-access MAF lists 223 somatic variants for this specimen: 149 protein-altering or splice-affecting, 67 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 67, Frame Shift Del 5, Nonsense Mutation 4, RNA 3, Intron 2, Splice Region 2, 3'UTR 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 81/184 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs772110575, COSV55879949, COSV56003293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.1672C>T p.L558F | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.798); catalogued as COSV52394737; called by muse, mutect2, varscan2
- ADGRV1 | c.8203A>T p.N2735Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV67995958; called by muse, mutect2
- AHNAK | c.4636G>A p.V1546M | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as COSV57231858; called by muse, mutect2, varscan2
- ANK2 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.665); catalogued as COSV52190350; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1277A>T p.D426V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs1447790407, COSV51859326; called by muse, mutect2, varscan2
- ARHGAP29 | c.1603T>G p.F535V | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.062); catalogued as COSV53117372, COSV99558452; called by muse, mutect2, varscan2
- ASB7 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV58404655; called by muse, mutect2, varscan2
- ATP6AP2 | c.300+1G>T p.X100_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as COSV65798402; called by muse, mutect2, varscan2
- ATR | c.7435G>A p.E2479K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100638161, COSV63391833, COSV63392961; called by muse, mutect2, varscan2
- C6 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54719415; called by muse, mutect2, varscan2
- C7orf31 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs531648664, COSV52216035; called by muse, mutect2, varscan2
- CACNA1A | c.871T>C p.W291R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64213280; called by muse, mutect2
- CCDC14 | c.446A>G p.E149G (on ENST00000488653; = p.E101G on NM_022757.5) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV59948190; called by muse, mutect2, varscan2
- CD99L2 | c.403C>A p.R135S | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.573); catalogued as COSV100691890, COSV60935265; called by muse, mutect2
- CDH16 | c.2186C>A p.T729N | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs1168084648, COSV55339978; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV62577913; called by muse, mutect2
- CEMIP2 | c.3181G>A p.V1061I | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138339130; called by muse, varscan2
- CLUH | c.2456G>T p.R819L (on ENST00000435359; = p.R858L on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70930154; called by muse, mutect2, varscan2
- CPA3 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56045232, COSV56047600; called by muse, mutect2, varscan2
- CPB1 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51577184; called by muse, mutect2
- CSMD3 | c.7335G>A p.M2445I (on ENST00000297405 / NM_001363185.1; = p.M2341I on NM_052900.3) | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1220708092, COSV52328590, COSV99850194; called by muse, mutect2, varscan2
- CSMD3 | c.3922G>T p.G1308C (on ENST00000297405 / NM_001363185.1; = p.G1204C on NM_052900.3) | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1355008081, COSV52107783; called by muse, mutect2, varscan2
- DAXX | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs573854582, COSV56473040; called by muse, mutect2, varscan2
- DEPDC1B | c.659A>T p.N220I | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54013416; called by muse, mutect2, varscan2
- DLEC1 | c.2198C>T p.S733F | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.062); catalogued as COSV57307056; called by muse, mutect2, varscan2
- DMKN | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV60087194, COSV60090114; called by muse, mutect2, varscan2
- DNAAF1 | c.1406C>A p.P469Q | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.483); catalogued as COSV100533416; called by muse, mutect2, varscan2
- DOCK7 | c.1955A>G p.H652R | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1389109627, COSV52022171; called by muse, mutect2, varscan2
- DYNC1I1 | c.287T>C p.M96T | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV61472065; called by muse, mutect2, varscan2
- E4F1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57041484; called by muse, mutect2, varscan2
- EDN3 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs750818786, COSV61110417; called by muse, mutect2, varscan2
- EFNB1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as rs755591908, COSV52661811; called by mutect2, varscan2
- EID2 | c.416A>T p.Y139F | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.442); catalogued as COSV66811086; called by muse, mutect2, varscan2
- EPPK1 | c.6025G>C p.V2009L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV73262412; called by muse, mutect2, varscan2
- EVPL | c.1882G>C p.G628R | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV56916447; called by muse, mutect2, varscan2
- FAM135B | c.1876G>T p.G626W | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV99417390; called by muse, mutect2, varscan2
- FAM151A | c.49G>C p.A17P | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV56366484; called by muse, mutect2
- FAM155A | c.16T>C p.W6R | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.33); catalogued as COSV65588739; called by muse, mutect2
- FLT4 | c.4049C>A p.S1350Y | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.326); catalogued as COSV56123434; called by muse, mutect2, varscan2
- FPGT | c.1276G>T p.V426L | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV63846210; called by muse, mutect2, varscan2
- GABRA2 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as COSV62920263; called by muse, mutect2, varscan2
- GCG | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 52/370 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as COSV64961994, COSV64962310; called by muse, mutect2, varscan2
- GIMAP6 | c.706T>C p.Y236H | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV61033265, COSV61034923; called by muse, mutect2, varscan2
- GUCY1A1 | c.1264C>A p.Q422K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56656826; called by muse, mutect2, varscan2
- HARS2 | c.197T>G p.L66R | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV56909637; called by muse, mutect2, varscan2
- HTR1A | c.458C>A p.A153D | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV60503064; called by muse, mutect2
- HUWE1 | c.5103G>T p.E1701D | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53364935; called by muse, mutect2, varscan2
- IFNA14 | c.105G>T p.R35S | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); catalogued as COSV66516512; called by muse, mutect2, varscan2
- IL16 | c.3151C>T p.L1051F (on ENST00000302987 / NM_172217.5; = p.L350F on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57268489; called by muse, mutect2
- KLHL1 | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as rs1566582366, COSV64785119; called by muse, mutect2, varscan2
- LCT | c.962G>A p.S321N | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV51557986; called by muse, mutect2, varscan2
- LHCGR | c.1562C>A p.T521N | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as rs1558798275, COSV54303551; called by muse, mutect2, varscan2
- LMBRD2 | c.2068G>A p.D690N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV56953008; called by muse, mutect2
- LMOD1 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66173984; called by muse, mutect2, varscan2
- LRRC7 | c.4559C>G p.T1520S (on ENST00000651989 / NM_001370785.2; = p.T1440S on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV50638051; called by muse, mutect2, varscan2
- LRRTM3 | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV63672298; called by muse, mutect2, varscan2
- LRRTM4 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as rs754661109, COSV101297751, COSV69141392, COSV69142654; called by muse, mutect2, varscan2
- LSS | c.1021A>G p.T341A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.101); catalogued as COSV62702895; called by muse, mutect2, varscan2
- LZTS1 | c.1120G>T p.G374C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV99742542, COSV99742982; called by muse, mutect2
- MAGEA6 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61449050, COSV61449346; called by muse, mutect2, varscan2
- MALT1 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 15/176 reads (9%) | catalogued as COSV61936722; called by muse, mutect2
- MAPK12 | c.771G>A p.E257= | Splice Region (SNP) | VAF 17/136 reads (13%) | catalogued as COSV53135998; called by muse, mutect2, varscan2
- MAST3 | c.312G>A p.S104= | Splice Region (SNP) | VAF 4/23 reads (17%) | catalogued as COSV53226984; called by muse, mutect2, varscan2
- MEAK7 | c.1076T>C p.L359P | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1186469679, COSV59145629; called by muse, mutect2
- MYBPC1 | c.622G>T p.V208L (on ENST00000550270 / NM_206820.2; = p.V233L on NM_002465.4) | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV62257914; called by muse, mutect2, varscan2
- MYH1 | c.2330T>C p.L777P | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs929288456, COSV56857729; called by muse, mutect2, varscan2
- MYOCD | c.1866T>A p.N622K | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV58512935; called by muse, mutect2, varscan2
- MYPN | c.3427A>G p.T1143A | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1307645556, COSV62740017; called by muse, mutect2, varscan2
- NAP1L2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65172323, COSV65173117; called by muse, mutect2
- NCAPD3 | c.3467T>A p.L1156H | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73244933; called by muse, mutect2, varscan2
- NOP10 | c.152G>C p.R51P | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV60995909; called by muse, mutect2, varscan2
- NR0B1 | c.128G>T p.C43F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); catalogued as COSV66764873; called by muse, mutect2, varscan2
- OR2F1 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV67332130; called by muse, mutect2, varscan2
- OR5C1 | c.367G>C p.A123P | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65456768; called by muse, mutect2
- OR6F1 | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57469525; called by muse, mutect2, varscan2
- OTUD5 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782666250, COSV50238565; called by muse, mutect2, varscan2
- PAQR8 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767947391, COSV62443752; called by muse, mutect2, varscan2
- PATJ | c.5120C>G p.A1707G | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV64506904; called by muse, mutect2, varscan2
- PCDH11X | c.1540A>T p.S514C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV53506571; called by muse, mutect2, varscan2
- PCDH19 | c.1565A>T p.N522I | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55272039; called by muse, mutect2, varscan2
- PCDHA4 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV63538719; called by muse, mutect2, varscan2
- PDE1C | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 29/308 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1231777861, COSV58516426, COSV58529809; called by muse, mutect2, varscan2
- PEX5L | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 28/476 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55858306; called by muse, mutect2
- PIK3CD | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1265306349, COSV63132059; called by muse, mutect2, varscan2
- PIK3CG | c.636G>T p.W212C | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV63254013; called by muse, mutect2, varscan2
- PRDM1 | c.1880G>A p.G627E | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64844921, COSV64847162; called by muse, mutect2, varscan2
- PRF1 | c.478C>A p.Q160K | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV100942489; called by muse, mutect2
- PRRG3 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV64851560; called by muse, mutect2, varscan2
- PSG4 | c.1124C>G p.S375* | Nonsense Mutation (SNP) | VAF 43/333 reads (13%) | catalogued as rs1420792080, COSV54941388; called by muse, mutect2, varscan2
- PXDN | c.393G>C p.K131N | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as COSV53246775, COSV99414735; called by muse, mutect2
- RAB40AL | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.532); catalogued as COSV54434136; called by muse, mutect2, varscan2
- REG1B | c.476C>A p.S159Y | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59308060; called by muse, mutect2, varscan2
- REG1B | c.475T>A p.S159T | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV59308074; called by muse, mutect2, varscan2
- RNASE11 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.75); catalogued as COSV60088428; called by muse, mutect2, varscan2
- RPUSD1 | c.82C>G p.R28G | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.925); catalogued as rs775498059, COSV50102591; called by muse, mutect2, varscan2
- RTTN | c.3205G>T p.A1069S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.085); catalogued as COSV55352555; called by muse, mutect2, varscan2
- RTTN | c.3204G>T p.M1068I | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV55352564; called by muse, mutect2, varscan2
- RYR2 | c.12892G>A p.V4298M | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as rs745927659, CM108884, COSV63710483, COSV63711482; called by muse, mutect2, varscan2
- SCAPER | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.8); catalogued as COSV100237476, COSV57754755; called by muse, mutect2, varscan2
- SHOC1 | c.1357G>A p.D453N | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.052); catalogued as rs1193031323, COSV59507518; called by muse, mutect2, varscan2
- SLC17A3 | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as COSV57761647; called by muse, mutect2, varscan2
- SLC23A3 | c.177G>A p.M59I | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV55409665; called by muse, mutect2, varscan2
- SLC28A1 | c.1132G>C p.A378P | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54486534; called by muse, mutect2, varscan2
- SLC4A1 | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs1222836115, COSV52263439; called by muse, mutect2, varscan2
- SLC9C1 | c.523A>T p.S175C | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV59893780; called by muse, mutect2, varscan2
- SNX33 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs367776246; called by mutect2, varscan2
- SOWAHD | c.873G>T p.K291N | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV59649988; called by muse, mutect2, varscan2
- SP140 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.578); catalogued as rs1228036460, COSV59455427; called by muse, mutect2, varscan2
- SPANXN1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100979451, COSV65122719; called by muse, mutect2, varscan2
- SRGAP3 | c.2309C>T p.S770L | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as rs753859975, COSV64540402; called by muse, mutect2, varscan2
- SSX5 | c.510G>T p.E170D (on ENST00000347757 / NM_175723.1; = p.E211D on NM_021015.4) | Missense Mutation (SNP) | VAF 81/584 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV61254677; called by muse, mutect2, varscan2
- TAFA3 | c.32C>T p.T11M | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.086); catalogued as rs750381184, COSV62625188; called by muse, mutect2, varscan2
- TGS1 | c.1696A>T p.N566Y | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV52703416; called by muse, mutect2, varscan2
- TJP1 | c.4894G>C p.V1632L | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as rs1443418679, COSV62046837; called by muse, mutect2, varscan2
- TLL1 | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 47/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50327927; called by muse, mutect2, varscan2
- TLR4 | c.180C>G p.D60E (on ENST00000355622 / NM_138554.5; = p.D20E on NM_003266.4) | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62924316; called by muse, mutect2, varscan2
- TMPRSS15 | c.1267C>A p.L423I | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53049803, COSV53051366; called by muse, mutect2, varscan2
- TRIM48 | c.77A>T p.Q26L | Missense Mutation (SNP) | VAF 96/372 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV70163374; called by muse, mutect2, varscan2
- TRIM9 | c.1372G>T p.A458S | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV53616839, COSV53625265; called by muse, mutect2, varscan2
- TRIML2 | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV58719901; called by muse, mutect2, varscan2
- TRIML2 | c.697A>T p.S233C | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as COSV58719914; called by muse, mutect2, varscan2
- TRMT6 | c.1041G>C p.Q347H | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV52545612; called by muse, mutect2, varscan2
- TRO | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51507139; called by muse, mutect2, varscan2
- TRRAP | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV62855058; called by muse, mutect2, varscan2
- TTN | c.80560C>A p.H26854N (on ENST00000591111; = p.H19430N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | PolyPhen benign (0.012); catalogued as COSV60367257; called by muse, mutect2
- TUBGCP2 | c.2048G>T p.R683L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV53303435, COSV53307526; called by muse, mutect2, varscan2
- UNC45A | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772800749, COSV67817718; called by muse, mutect2, varscan2
- UNC5D | c.2615G>T p.G872V | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54838898; called by muse, mutect2, varscan2
- USH2A | c.12917T>A p.L4306H | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.819); catalogued as COSV56442288; called by muse, mutect2, varscan2
- VARS1 | c.2290C>T p.R764W | Missense Mutation (SNP) | VAF 50/242 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs55786236, COSV63305174; called by muse, mutect2, varscan2
- VPS13D | c.9839T>G p.I3280S | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50690858; called by muse, mutect2, varscan2
- WDR3 | c.2395T>A p.Y799N | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV60469103; called by muse, mutect2, varscan2
- WNT10B | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1179805368, COSV56406457; called by muse, mutect2, varscan2
- ZFHX4 | c.6582C>G p.N2194K | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50520031, COSV51498045; called by muse, mutect2, varscan2
- ZIC3 | c.87C>A p.N29K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.024); catalogued as COSV54977357; called by muse, mutect2, varscan2
- ZIC3 | c.88C>A p.R30S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.987); catalogued as COSV54975970, COSV99798147; called by muse, mutect2, varscan2
- ZNF267 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV56256382; called by muse, mutect2, varscan2
- ZNF442 | c.767A>G p.E256G | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV54423494; called by muse, mutect2, varscan2
- ZNF461 | c.1606C>G p.Q536E | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV64455409; called by muse, mutect2, varscan2
- ZNF536 | c.364G>T p.D122Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62834769; called by muse, mutect2, varscan2
- ZNF676 | c.1124G>C p.G375A (on ENST00000650058; = p.G343A on NM_001001411.3) | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101236211, COSV68094205, COSV68095102; called by muse, mutect2
- COL4A6 | c.1735G>T p.G579* | Nonsense Mutation (SNP) | VAF 27/235 reads (11%) | called by muse, mutect2, varscan2
- MPO | c.904del p.R302Afs*132 | Frame Shift Del (DEL) | VAF 15/94 reads (16%) | called by mutect2, pindel, varscan2
- MYO16 | c.2113del p.T705Qfs*8 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- SDC3 | c.564del p.S189Afs*15 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- SLC6A6 | c.617del p.L206Cfs*11 | Frame Shift Del (DEL) | VAF 30/167 reads (18%) | called by mutect2, pindel, varscan2
- TRBV4-1 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZNF18 | c.906del p.H303Tfs*23 | Frame Shift Del (DEL) | VAF 29/171 reads (17%) | called by mutect2, pindel, varscan2
- ABCD4 | c.417C>T p.I139= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs770164744, COSV53991811; called by muse, mutect2, varscan2
- ADAMTS7 | c.2193C>T p.A731= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs765182422, COSV66309550; called by muse, mutect2, varscan2
- AMPD1 | c.771C>A p.V257= | Silent (SNP) | VAF 22/170 reads (13%) | catalogued as COSV62419254; called by muse, mutect2, varscan2
- ANK2 | c.537G>C p.V179= | Silent (SNP) | VAF 27/200 reads (14%) | catalogued as COSV52190334; called by muse, mutect2, varscan2
- ANO10 | c.489G>A p.T163= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as rs770151711, COSV52736673; called by muse, mutect2, varscan2
- ANXA6 | c.192C>G p.S64= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV62905690, COSV62908553; called by muse, mutect2, varscan2
- ATP4A | c.1101C>T p.C367= | Silent (SNP) | VAF 25/249 reads (10%) | catalogued as rs766064812, COSV52872003; called by muse, mutect2, varscan2
- BNIP5 | c.72C>G p.A24= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs1158832590, COSV71325843, COSV71325870; called by muse, mutect2, varscan2
- CD99L2 | c.402C>A p.G134= | Silent (SNP) | VAF 14/235 reads (6%) | catalogued as COSV60938663; called by muse, mutect2
- CEP250 | c.7122C>T p.I2374= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV61174798; called by muse, mutect2, varscan2
- CHRNA1 | c.795C>A p.I265= (on ENST00000261007 / NM_001039523.3; = p.I240= on NM_000079.4) | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as COSV53685407; called by muse, mutect2, varscan2
- CYFIP2 | c.2488C>A p.R830= (on ENST00000616178 / NM_001291722.2; = p.R805= on NM_014376.4) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV56638212; called by muse, mutect2
- DNAH5 | c.9124C>A p.R3042= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV54246587, COSV54254136; called by mutect2, varscan2
- FSTL5 | c.1518T>A p.A506= | Silent (SNP) | VAF 41/253 reads (16%) | catalogued as COSV60232683; called by muse, mutect2, varscan2
- GALNT17 | c.1632C>A p.V544= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV61193532; called by muse, mutect2, varscan2
- GAS6 | c.1890G>T p.P630= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV100580934, COSV100580945; called by muse, mutect2, varscan2
- GSR | c.663C>T p.S221= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as rs748916113, COSV55323391; called by muse, mutect2, varscan2
- HSPA8 | c.1404C>T p.P468= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV57086661; called by muse, mutect2, varscan2
- HUNK | c.1575G>T p.P525= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as COSV54234766; called by muse, mutect2, varscan2
- IGF2BP1 | c.1326A>T p.A442= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as COSV51736376; called by muse, mutect2, varscan2
- INMT | c.453G>A p.P151= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs370569103; called by muse, mutect2, varscan2
- KCND1 | c.783G>T p.R261= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV54416135; called by mutect2, varscan2
- KRT72 | c.1485C>T p.P495= | Silent (SNP) | VAF 43/234 reads (18%) | catalogued as rs1452412212, COSV53377008; called by muse, mutect2, varscan2
- LILRA4 | c.453G>A p.R151= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV52495070; called by muse, mutect2
- LLCFC1 | c.324G>A p.S108= (on ENST00000458732; = p.S77= on NM_178829.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/171 reads (17%) | catalogued as rs767114431, COSV62338099; called by muse, mutect2, varscan2
- MAGEA11 | c.712C>A p.R238= | Silent (SNP) | VAF 34/229 reads (15%) | catalogued as COSV60756605, COSV60759050; called by muse, mutect2, varscan2
- MRC1 | c.3174T>C p.G1058= | Silent (SNP) | VAF 27/197 reads (14%) | called by muse, mutect2, varscan2
- MYBPC1 | c.2232T>A p.I744= (on ENST00000550270 / NM_206820.2; = p.I769= on NM_002465.4) | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV62257927; called by muse, mutect2
- NDST4 | c.1236A>G p.P412= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV52138522; called by muse, mutect2
- NETO1 | c.1261C>A p.R421= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs574511728, COSV55001768, COSV55002830; called by muse, mutect2
- NEXMIF | c.3951C>A p.S1317= | Silent (SNP) | VAF 35/180 reads (19%) | catalogued as COSV50133148; called by muse, mutect2, varscan2
- NRK | c.4011C>T p.H1337= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV54607502; called by muse, mutect2
- NRXN2 | c.3538C>A p.R1180= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as COSV55447523, COSV55463973; called by muse, mutect2, varscan2
- OR2B11 | c.933G>A p.R311= | Silent (SNP) | VAF 53/397 reads (13%) | catalogued as COSV59511630; called by muse, mutect2, varscan2
- OR8H1 | c.174C>A p.P58= | Silent (SNP) | VAF 36/259 reads (14%) | catalogued as COSV100476743; called by muse, mutect2, varscan2
- OSBPL6 | c.1365C>T p.V455= | Silent (SNP) | VAF 6/83 reads (7%) | catalogued as COSV51931266; called by muse, mutect2
- PAX1 | c.1149C>A p.G383= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV68272060, COSV68273544; called by muse, mutect2
- PCDH9 | c.1929T>C p.F643= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as rs1405108320, COSV60592893; called by muse, mutect2, varscan2
- PLEC | c.10938C>T p.T3646= (on ENST00000322810 / NM_201380.4; = p.T3536= on NM_000445.5) | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as COSV59698298; called by muse, mutect2, varscan2
- PRDX6 | c.429G>C p.L143= | Silent (SNP) | VAF 42/325 reads (13%) | catalogued as COSV61166376; called by muse, mutect2, varscan2
- PREX2 | c.2076G>A p.R692= | Silent (SNP) | VAF 22/230 reads (10%) | catalogued as COSV55770749; called by muse, mutect2
- PSMD3 | c.477C>G p.L159= | Silent (SNP) | VAF 28/207 reads (14%) | catalogued as COSV52859946, COSV99228118; called by muse, mutect2, varscan2
- RIPK4 | c.1566G>T p.P522= (on ENST00000352483; = p.P474= on NM_020639.3) | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as rs753627941, COSV60186839, COSV60191475; called by muse, mutect2, varscan2
- ROCK2 | c.2565A>C p.A855= | Silent (SNP) | VAF 23/242 reads (10%) | catalogued as rs776881617, COSV59965823; called by muse, mutect2
- RPS6KA6 | c.1833T>C p.L611= | Silent (SNP) | VAF 50/347 reads (14%) | catalogued as COSV53124015, COSV53127307; called by muse, mutect2, varscan2
- RPS9 | c.570C>T p.D190= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs142681896, COSV57190636; called by muse, mutect2, varscan2
- RSF1 | c.1992A>G p.V664= | Silent (SNP) | VAF 33/201 reads (16%) | catalogued as COSV57846145; called by muse, mutect2, varscan2
- SLC14A2 | c.726T>C p.I242= | Silent (SNP) | VAF 34/233 reads (15%) | catalogued as rs368391173; called by muse, mutect2, varscan2
- SLC17A6 | c.168G>A p.K56= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV54141781; called by mutect2, varscan2
- SLC22A16 | c.1558T>C p.L520= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as COSV57934199; called by muse, mutect2, varscan2
- SLITRK4 | c.345C>T p.N115= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as COSV62025785, COSV62026257; called by muse, mutect2, varscan2
- SMG7 | c.396A>G p.K132= | Silent (SNP) | VAF 30/272 reads (11%) | catalogued as COSV61634500; called by muse, mutect2, varscan2
- SSH3 | c.1947C>T p.S649= | Silent (SNP) | VAF 8/127 reads (6%) | catalogued as rs373974857; called by muse, mutect2
- TDRD5 | c.1467G>T p.R489= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as COSV54238796, COSV54251024; called by muse, mutect2, varscan2
- TMPPE | c.33G>A p.A11= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as rs753755429, COSV56564960; called by muse, mutect2, varscan2
- TSNARE1 | c.873G>A p.T291= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs368218203, COSV56173337; called by muse, mutect2, varscan2
- USH2A | c.12918C>A p.L4306= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as COSV56442257; called by muse, mutect2, varscan2
- VANGL1 | c.801G>T p.L267= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV100048712; called by muse, mutect2, varscan2
- VPS13C | c.8925A>C p.A2975= (on ENST00000644861 / NM_020821.3; = p.A2932= on NM_017684.5) | Silent (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2, varscan2
- WAS | c.1396C>T p.L466= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100939420; called by muse, mutect2, varscan2
- WT1 | c.732C>T p.F244= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV60084520; called by muse, mutect2, varscan2
- ZDHHC15 | c.507C>A p.S169= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV64900711, COSV64903836; called by muse, mutect2, varscan2
- ZFHX3 | c.1764G>A p.L588= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV51737415; called by muse, mutect2, varscan2
- ZNF320 | c.1173C>G p.G391= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as COSV67089022; called by muse, mutect2, varscan2
- ZNF536 | c.3753G>A p.P1251= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs573555056, COSV62820378; called by muse, mutect2, varscan2
- ZNF71 | c.1290G>T p.R430= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV60150416; called by muse, mutect2, varscan2
- ZNF778 | c.225C>T p.Y75= | Silent (SNP) | VAF 11/143 reads (8%) | catalogued as rs747976804, COSV60602892; called by muse, mutect2
- AC024940.1 | n.2748C>A | RNA (SNP) | VAF 13/128 reads (10%) | called by muse, mutect2, varscan2
- ACADM | c.286+220A>T | Intron (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100897581; called by muse, mutect2, varscan2
- CEACAM18 | c.-1C>A | 5'UTR (SNP) | VAF 4/40 reads (10%) | catalogued as COSV101140087, COSV67283430; called by muse, mutect2
- ERCC6 | c.1397+7269C>T | Intron (SNP) | VAF 17/106 reads (16%) | catalogued as rs375732850; called by muse, mutect2, varscan2
- FAM74A3 | n.180G>A | RNA (SNP) | VAF 7/50 reads (14%) | catalogued as rs367928497; called by muse, mutect2, varscan2
- GHRHR | c.*2C>G | 3'UTR (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100396408; called by muse, mutect2, varscan2
- RPL23AP42 | n.375C>T | RNA (SNP) | VAF 41/176 reads (23%) | catalogued as rs1394683576; called by muse, mutect2, varscan2
